Surgical pathology report (de-identified scan), TCGA case TCGA-Q9-A6FU, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Emory University, specimen TCGA-Q9-A6FU-01A (Primary Tumor).

[page 1 of 5]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date:
Document Status:
Document Title: Histology
Performed By:
Verified By:
Encounter info:
Contributor system:

ICD-O-3
Carcinoma, squamous cell HQ
8070/3
Site CCF
Distal third esophagus
C15.5
JUN 6/17/13

* Final Report *

(Verified)

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

Acc #:

DOB:

Gender:

(Age:

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. CELIAC LYMPH NODE, EXCISION:

- METASTATIC CARCINOMA IN ONE OF ONE LYMPH NODE, 1/1.

B. LEFT GASTRIC LYMPH NODE, EXCISION:

- METASTATIC CARCINOMA IN ONE OF TWO LYMPH LYMPH NODES, 1/2.

C. LYMPH NODE, RIGHT # 9, EXCISION:

- TWO LYMPH NODES, NEGATIVE FOR NEOPLASM, 0/2.

D. LYMPH NODE, LEVEL 7, EXCISION:

- TWO LYMPH NODES, NEGATIVE FOR NEOPLASM, 0/2.

E. DISTAL ESOPHAGUS/PROXIMAL STOMACH, ESOPHAGECTOMY:

- SQUAMOUS CELL CARCINOMA (AT LEAST 4.9 CM), MODERATELY DIFFERENTIATED.

Printed by:

Printed on:

Page 1 of 5

(Continued)

Date Reported		

[page 2 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

: regarding

Anat Path Reports

* Final Report *

- LYMPHOVASCULAR AND PERINEURAL INVASION ARE PRESENT.
- METASTATIC CARCINOMA IN TWO OF TWENTY-ONE LYMPH NODES, 2/21 (TOTAL COUNT: 4/28).
- MARGINS, NEGATIVE; TUMOR IS LESS THAN 0.1 CM (<1MM) FROM INKED ADVENTITIAL SURFACE.
- SEE SYNOPTIC REPORT.

F. MOST PROXIMAL ESOPHAGUS, ESOPHAGECTOMY:

- SEGMENT OF ESOPHAGEAL WALL, NEGATIVE FOR NEOPLASM.

Electronically Signed by

Synoptic Worksheet

E. Distal esophagus and proximal stomach, one stitch is on the esophageal margin, two stitches are on the gastric margin:

Clinical History:	Not known
Specimen:	Esophagus Proximal stomach
Procedure:	Esophagectomy
Tumor Site:	Distal esophagus (lower thoracic esophagus) Esophagogastric junction (EGJ) Proximal stomach and esophagogastric junction
Relationship of Tumor to Esophagogastric Junction:	Tumor midpoint is located at the esophagogastric junction
Distance of tumor center from esophagogastric junction:	2.6 cm
Tumor Size:	Greatest dimension: 4.9 cm Additional dimension: 2.8 cm
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G2: Moderately differentiated
Microscopic Tumor Extension:	Tumor invades through the muscularis propria into the periesophageal soft tissue (adventitia)
Margins:	Proximal margin uninvolved by invasive carcinoma Proximal margin uninvolved by dysplasia Distal margin uninvolved by invasive carcinoma Distal margin uninvolved by dysplasia Circumferential (adventitial) margin or Deep margin uninvolved by invasive carcinoma
Treatment Effect:	No prior treatment
Lymph-Vascular Invasion:	Present

Printed by:

Printed on:

[page 3 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Perineural Invasion:	Present
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT3: Tumor invades adventitia
Regional Lymph Nodes (pN):	pN2: 3 to 6 nodes involved
	Number of regional lymph nodes examined: 28
	Number of regional lymph nodes involved: 4
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Gastritis: Chronic gastritis.

Clinical History

Ivor-Lewis esophagectomy. Esophageal cancer. Muscular dystrophy. GERD

Specimen(s) Received

A: Celiac lymph node
B: Left gastric node
C: Right #9 lymph node
D: Level 7 lymph node
E: Distal esophagus and proximal stomach, one stitch is on the esophageal margin, two stitches are on the gastric margin
F: Portion of esophagus; stitch on proximal margin

Gross Description

Five specimens are received fresh, each is labeled with the patient's name and medical record number.

Specimen A is received for intraoperative consultation and is labeled "celiac lymph node." It consists of a nodular fragment of fibrofatty tissue measuring 3.5 x 2.0 x 1.0 cm. There is a firm, white nodule identified with centralized fat necrosis and measuring 1.5 x 1.1 x 0.8 cm. The nodule is bisected and submitted entirely for frozen section diagnosis in cassette "A1FS." A touch prep is performed from the nodules. The remainder of the specimen is submitted, wrapped in lens paper in cassette "A2." Dictated by

Specimen B is received in formalin and is labeled "left gastric node." It consists of a nodular fragment of tissue measuring 1.0 x 0.8 x .3 cm. The specimen is submitted entirely in cassette "B1." Dictated by

Specimen C is received in formalin and is labeled "right #9 lymph node." It consists of two fragments of soft tissue ranging in size from 0.4 to 0.5 cm. The specimen is submitted entirely in cassette "C1." Dictated by

Specimen D is received in formalin and is labeled "level #7 lymph node." It consists of two fragments of grey-tan soft tissue ranging in size from 0.5 to 1.5 cm. The specimen is submitted entirely in cassette "D1." Dictated by

Specimen E is received fresh for intraoperative consultation and is labeled "distal esophagus and proximal stomach." It consists of an esophagogastrectomy specimen with attached fibroadipose tissue. The esophagus measures 5.5 cm in length and 2.0 cm in diameter. The stomach measures 12.5 cm in length and 12.0 cm in average circumference. A near circumferential firm white tumor spanning the GE junction. The tumor is 4.9 cm in length and has a maximum thickness of 2.8 cm. The tumor is 3.4 cm from the esophagus margin, 2.5 cm from the closest stomach margin and abuts the radial margin. The midpoint of the tumor is 2.6 cm from the EG junction. The adventitial surface is inked black. The esophageal margin and the closest stomach margin are

Printed by:
Printed on:

[page 4 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

submitted for frozen section diagnosis in cassettes "E1FS" and "E2FS" respectfully. The lumen of the esophagus is narrow measuring less than 0.4 cm in diameter. The stomach's mucosal surface over the lesion is ulcerated. The remaining mucosal surface of the stomach has a granular texture, is focally ulcerated and has normal appearing folds. Multiple possible lymph nodes are identified within the attached fibrofatty tissue ranging in size from 0.1 to 1.0 cm. A representative section of the lesion as well as uninvolved stomach are submitted to Tissue Procurement Services. Sections are submitted as stated below. Dictated by

Specimen F is received in formalin, labeled with the patient's name, medical record number as "portion of esophagus; stitch on proximal margin." Received is a segment of esophagus measuring 3.0 cm in length and 4.1 cm in greatest diameter. There is a suture present at the proximal margin. The adventitial surface, is mostly covered with adhesions. The mucosa is smooth and glistening. No masses or lesions are noted. There is a focal erythematous area along the proximal margin measuring 0.4 x 0.3 cm. The adventitia at the distal margin is inked orange and the remainder of the adventitia is inked blue. The proximal margin is shaved and submitted, "F1." "Additional representative longitudinal sections are submitted, "F2." Dictated by

CASSETTE SUMMARY:

E1FS:	Esophageal margin, shave
E2FS:	Stomach margin, shave (closest to lesion)
E3,E4:	Mass to include deepest area of invasion
E5,E6:	Mass at GE junction
E7:	Stomach ulceration and mass
E8:	Uninvolved stomach in relationship to mass
E9:	Uninvolved esophagus in relationship to mass
E10:	Uninvolved esophagus
E11:	Uninvolved stomach
E12:	Squamous columnar junction
E13:	Four possible lymph nodes, whole
E14:	Four possible lymph nodes, whole
E15:	Three possible lymph nodes, whole
E16:	Three possible lymph nodes, whole

Intraoperative Consult Diagnosis

A1FS:	CELIAC LYMPH NODE (FROZEN SECTION): SQUAMOUS CELL CARCINOMA. Frozen section results were communicated to the surgical team and were repeated back by Dr. on
E1FS-E2FS:	DISTAL ESOPHAGUS AND PROXIMAL STOMACH (FROZEN SECTION): MARGINS ARE NEGATIVE FOR CARCINOMA. Frozen section results were communicated to the surgical team and were repeated back by Dr. on

Pathologist:

Microscopic Description

Microscopic examination performed.

Printed by:

Printed on:

[page 5 of 5]
-Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Printed by:
Printed on:

Page 5 of 5
(End of Report)

Source: NCI Genomic Data Commons file 01b3587e-8a4f-42b5-a01a-cda203578a74 (TCGA-Q9-A6FU.AFFB9ED2-A395-4C25-A2AA-AE09CF996F1A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).